Gene-level copy-number profile of tumor specimen TCGA-24-1436-01A from TCGA case TCGA-24-1436, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.2 years (20,881 days).
Specimen TCGA-24-1436-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.279a61c4-12e9-4a4f-88bd-2cd122c43dea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1436-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 830 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ae9621f1-3f53-4a41-843d-f68ef106c4b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 6,967; copy number 2: 25,836; copy number 3: 19,180; copy number 4: 4,860; copy number 5: 1,151; copy number 6: 1,682; copy number 7: 30; copy number 8: 1; copy number 9: 4; copy number 11: 53; copy number 14: 11; copy number 20: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1436-01A-01D-0472-01): tumor purity 0.78, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,304,047–60,304,151, 1 gene: RNU6-806P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,947 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:108,534,355–114,261,226, 167 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr2:193,276,668–194,028,164, 5 genes, copy number 8–9: DNAJC17P1, SEC61GP1, AC074290.1, AC068135.2, AC068135.1.
- chr3:148,791,102–198,222,513, 894 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:33,547,754–35,796,550, 21 genes, copy number 5: RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1.
- chr8:52,110,839–144,605,816, 1,424 genes, copy number 5–7 (broad region; genes not listed).
- chr9:14,475–22,214,672, 323 genes, copy number 6 (broad region; genes not listed).
- chr11:77,878,720–78,418,348, 15 genes, copy number 5 (within-gene range 3–5): INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1.
- chr11:121,238,304–121,362,865, 4 genes, copy number 5: AP001124.1, RPS4XP12, SC5D, BMPR1AP2.
- chr15:98,282,075–98,547,728, 5 genes, copy number 7 (within-gene range 4–7): AC015722.1, AC015722.2, LINC02351, FAM169B, AC103968.1.
- chr18:22,647,582–26,657,401, 75 genes, copy number 11–20 (broad region; genes not listed).
- chr18:26,685,954–26,825,171, 4 genes, copy number 20: AC012588.1, PCAT18, U3, AC018371.1.
- chr21:15,263,421–15,880,069, 9 genes, copy number 5: AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP.
- chr21:16,035,413–16,035,509, 1 gene, copy number 5: RNU6-426P.

Autosomal genes at a single copy (total copy number 1): 4,548. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
